Somatic mutation profile of tumor specimen TCGA-FD-A3NA-01A (aliquot TCGA-FD-A3NA-01A-11D-A21A-08) from TCGA case TCGA-FD-A3NA, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 60.1 years (21,936 days).
Specimen TCGA-FD-A3NA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e567933-fa77-4e4e-bfb9-dfe05af7a9b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3NA-10A (Blood Derived Normal), aliquot TCGA-FD-A3NA-10A-01D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb7a98a5-e72d-47ee-8923-90742590a60b

The open-access MAF lists 179 somatic variants for this specimen: 136 protein-altering or splice-affecting, 37 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 37, Nonsense Mutation 11, Intron 3, Splice Site 2, Translation Start Site 1, RNA 1, Splice Region 1, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1411C>G p.P471A | Missense Mutation (SNP) | VAF 27/51 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as COSV55937763; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.3280G>A p.E1094K | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV55782874, COSV55788452; called by muse, mutect2, varscan2
- AGPS | c.1895C>G p.S632C | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51565060; called by muse, mutect2, varscan2
- AKAP1 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV58470741; called by muse, mutect2, varscan2
- AMZ1 | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.396); catalogued as COSV56687311; called by muse, mutect2, varscan2
- ANKRD54 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV53236507; called by muse, mutect2, varscan2
- APOBEC1 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV57549206; called by muse, mutect2, varscan2
- ASH1L | c.3574C>T p.H1192Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV64208904; called by muse, mutect2, varscan2
- BRINP2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs763478469, COSV64177954; called by muse, mutect2, varscan2
- C2CD3 | c.2431G>A p.V811M | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58094034; called by muse, mutect2, varscan2
- CASP4 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV67744506; called by muse, mutect2, varscan2
- CCDC33 | c.291G>C p.E97D | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV58352873; called by muse, mutect2, varscan2
- CCDC61 | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54428928; called by muse, mutect2, varscan2
- CCDC88A | c.5475G>C p.L1825F (on ENST00000436346 / NM_001365480.1; = p.L1797F on NM_018084.5) | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV55063176; called by muse, mutect2, varscan2
- CD163 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440209201, COSV63133302; called by muse, mutect2, varscan2
- CENPE | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1197719147, COSV54382561; called by muse, mutect2, varscan2
- CENPE | c.1966-1G>A p.X656_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | catalogued as COSV54382574; called by muse, mutect2, varscan2
- CFHR1 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.482); catalogued as COSV57627465; called by muse, mutect2, varscan2
- CHAT | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as rs751461280, COSV60326568; called by muse, mutect2, varscan2
- CLDN1 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV55044256; called by muse, mutect2, varscan2
- COL6A6 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62022955; called by muse, mutect2, varscan2
- CPA3 | c.463T>C p.Y155H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.636); catalogued as COSV56045542; called by muse, mutect2, varscan2
- CSMD3 | c.10859C>A p.S3620* (on ENST00000297405 / NM_001363185.1; = p.S3451* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV52333333, COSV99842538; called by muse, mutect2, varscan2
- CYP4B1 | c.1280C>G p.S427C | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs1359422919, COSV54721677, COSV54724067; called by muse, mutect2, varscan2
- DCST2 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV55052264, COSV55055013; called by muse, varscan2
- DEPDC1 | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332462539, COSV63958450; called by muse, mutect2, varscan2
- DEPDC5 | c.2882C>T p.S961L (on ENST00000400246; = p.S1030L on NM_014662.5) | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56697057, COSV56699618; called by muse, mutect2, varscan2
- DHX29 | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as COSV99287380; called by muse, mutect2
- DOCK9 | c.5509G>C p.D1837H (on ENST00000376460 / NM_001366676.2; = p.D1838H on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV59632228; called by muse, mutect2, varscan2
- DSCAM | c.4444G>A p.E1482K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as COSV68028347, COSV68031762; called by muse, mutect2, varscan2
- ENPP2 | c.780A>G p.L260= | Splice Region (SNP) | VAF 18/34 reads (53%) | catalogued as rs1028228576, COSV50017670; called by muse, mutect2, varscan2
- EPHB4 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.268); catalogued as COSV62269160; called by muse, mutect2
- FAT4 | c.2012C>G p.S671* | Nonsense Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV67881889; called by muse, varscan2
- FAT4 | c.2926C>T p.L976F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs367831459; called by muse, varscan2
- FAT4 | c.2933C>A p.S978Y | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67888900; called by muse, varscan2
- FAT4 | c.3187C>G p.Q1063E | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.939); catalogued as COSV67888920; called by muse, varscan2
- FAT4 | c.3260C>G p.T1087S | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); catalogued as COSV67888925; called by muse, varscan2
- FBN1 | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV57319297; called by muse, mutect2, varscan2
- FBXO38 | c.3556G>A p.D1186N (on ENST00000340253 / NM_205836.3; = p.D1111N on NM_030793.5) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57028429; called by muse, mutect2, varscan2
- FBXO48 | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV58144328, COSV58149354; called by muse, mutect2, varscan2
- FGA | c.1889G>A p.R630K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.899); catalogued as COSV57396955; called by muse, mutect2, varscan2
- FLNC | c.4612G>C p.D1538H | Missense Mutation (SNP) | VAF 63/362 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100367537, COSV57957201; called by muse, mutect2, varscan2
- FMNL2 | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56496736; called by muse, mutect2, varscan2
- FNDC1 | c.1889C>G p.S630C | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV51939629; called by muse, mutect2, varscan2
- GBA | c.770A>T p.D257V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59169978; called by muse, mutect2, varscan2
- GPR45 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.057); catalogued as COSV51524407; called by muse, mutect2, varscan2
- HDDC2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV59532421; called by muse, mutect2, varscan2
- HECTD2 | c.1323G>C p.L441F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53221665; called by muse, mutect2, varscan2
- HEXIM1 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60176782, COSV60177236; called by muse, mutect2, varscan2
- HS3ST4 | c.949A>C p.K317Q | Missense Mutation (SNP) | VAF 89/290 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV58818259; called by muse, mutect2, varscan2
- HSPA4L | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56546044; called by muse, mutect2, varscan2
- IDH1 | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV61626634; called by muse, mutect2, varscan2
- IGSF10 | c.1294G>C p.D432H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV56786417; called by muse, mutect2, varscan2
- IKBKB | c.1987-1G>C p.X663_splice | Splice Site (SNP) | VAF 53/243 reads (22%) | catalogued as COSV60597695; called by muse, mutect2, varscan2
- INTS4 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1259922873, COSV71088840; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.157); catalogued as COSV56441278; called by muse, mutect2, varscan2
- JHY | c.841dup p.R281Kfs*35 | Frame Shift Ins (INS) | VAF 68/181 reads (38%) | catalogued as rs974240509; called by mutect2, varscan2
- KDM4B | c.2204C>G p.S735C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.421); catalogued as COSV50224415; called by muse, mutect2, varscan2
- KIAA1522 | c.466C>T p.R156W (on ENST00000373480 / NM_001198972.2; = p.R215W on NM_020888.3) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771611424, COSV53865042; called by muse, varscan2
- LIG3 | c.963G>C p.L321F | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52008246; called by muse, mutect2, varscan2
- LRRCC1 | c.2830G>C p.E944Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV64483719, COSV64484291; called by muse, mutect2, varscan2
- LRRIQ3 | c.187A>G p.T63A | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs756419637, COSV63040699; called by muse, mutect2, varscan2
- LTF | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs573693534, COSV51608776; called by muse, mutect2, varscan2
- LVRN | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762068329, COSV100773441, COSV63497440; called by muse, mutect2, varscan2
- MARCHF6 | c.498G>C p.Q166H | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56882313; called by muse, mutect2, varscan2
- MFF | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/89 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.38); catalogued as COSV58825933; called by muse, mutect2, varscan2
- MMP25 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757540476, COSV60679837; called by muse, mutect2, varscan2
- MON2 | c.5119C>G p.P1707A | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.206); catalogued as COSV54808712; called by muse, mutect2, varscan2
- MTR | c.632A>G p.N211S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs546918671, COSV63968281; called by muse, mutect2, varscan2
- MUC16 | c.10400G>C p.G3467A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.281); catalogued as COSV67471853; called by muse, mutect2, varscan2
- MUC6 | c.5294C>T p.S1765F | Missense Mutation (SNP) | VAF 46/1476 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as rs751972606, COSV70142989; called by muse, mutect2
- N4BP2 | c.4981C>G p.L1661V | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV54702796; called by muse, mutect2, varscan2
- NCAN | c.2596G>A p.D866N | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53052432; called by muse, mutect2, varscan2
- NF1 | c.8474G>C p.R2825T (on ENST00000358273 / NM_001042492.3; = p.R2804T on NM_000267.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV62206250; called by muse, mutect2, varscan2
- NR3C1 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51541455; called by muse, mutect2
- NT5E | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs565537252, COSV57628646; called by muse, mutect2, varscan2
- OCLN | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62285476; called by muse, mutect2, varscan2
- OR3A2 | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV101375064, COSV101375104; called by mutect2, varscan2
- OR5W2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV60616499; called by muse, mutect2, varscan2
- PAN2 | c.605T>A p.M202K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV57754263; called by muse, mutect2, varscan2
- PARD3B | c.796A>C p.T266P | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62514531; called by muse, mutect2, varscan2
- PCDHB10 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.281); catalogued as COSV53379755; called by muse, mutect2, varscan2
- PCSK9 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56162656; called by muse, mutect2, varscan2
- PGM2L1 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs769630016, COSV53347401; called by muse, mutect2, varscan2
- PHKG2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV60312349; called by muse, mutect2, varscan2
- PHLPP1 | c.3849G>C p.L1283F | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53030437; called by muse, mutect2, varscan2
- PKP2 | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs558637427, COSV50733025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA8 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs906254987, COSV51651705; called by muse, mutect2, varscan2
- PLEKHF2 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV59541652; called by muse, mutect2, varscan2
- PLXNB1 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56490643; called by muse, mutect2, varscan2
- PLXNB2 | c.5478G>C p.Q1826H | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63782284; called by muse, varscan2
- PPARD | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV61100007; called by muse, mutect2, varscan2
- PPP2R3A | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs372883345; called by muse, mutect2, varscan2
- PSG3 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 173/525 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs545782001, COSV59504795; called by muse, mutect2, varscan2
- RBBP6 | c.4654A>G p.K1552E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.152); catalogued as COSV60505728; called by muse, mutect2, varscan2
- RBM10 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV61309648; called by muse, mutect2, varscan2
- RIMS2 | c.1082G>A p.R361Q (on ENST00000666250 / NM_001348490.2; = p.R169Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs917512575, COSV51688592; called by muse, mutect2, varscan2
- RTCA | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV53120825; called by muse, mutect2, varscan2
- SCAF4 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV54256365, COSV54256493; called by muse, mutect2, varscan2
- SEC24B | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs746367510, COSV54500862; called by muse, mutect2, varscan2
- SESN1 | c.1454G>C p.R485T (on ENST00000356644 / NM_001199933.1; = p.R544T on NM_014454.3) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57420947; called by muse, mutect2, varscan2
- SLC22A10 | c.1458G>C p.L486F | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as rs767126155, COSV60421631; called by muse, mutect2, varscan2
- SLFN5 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55481551; called by muse, mutect2, varscan2
- STAG2 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54351727, COSV54364695; called by muse, mutect2, varscan2
- SYTL2 | c.1320C>G p.I440M | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV60359867; called by muse, mutect2, varscan2
- TAF1D | c.203C>A p.S68* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100127006, COSV58680005; called by mutect2, varscan2
- TASOR2 | c.6701G>A p.R2234K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as rs1381217408, COSV60167839; called by muse, mutect2, varscan2
- TAZ | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM046065, COSV50010446; called by muse, mutect2, varscan2
- THAP4 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV67190655; called by muse, mutect2, varscan2
- TLR3 | c.1208C>A p.S403* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV57167625, COSV99711094; called by muse, mutect2, varscan2
- TOB1 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52150312, COSV99278966; called by muse, mutect2
- TRPV2 | c.693C>A p.N231K | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58428740; called by muse, mutect2, varscan2
- TTN | c.69092C>A p.T23031N (on ENST00000591111; = p.T15607N on NM_003319.4) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | PolyPhen benign (0.003); catalogued as COSV60113398; called by muse, mutect2, varscan2
- UACA | c.546del p.C183Vfs*4 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | catalogued as COSV59856472; called by mutect2, pindel, varscan2
- ULK4 | c.614T>C p.L205S | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754121302, COSV57211443; called by muse, mutect2, varscan2
- UROC1 | c.1879G>C p.V627L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52034226; called by muse, mutect2, varscan2
- USP8 | c.2097G>C p.K699N | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV56164951; called by muse, mutect2, varscan2
- VAC14 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV55754388; called by mutect2, varscan2
- VEZF1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.013); catalogued as COSV51968637; called by muse, mutect2, varscan2
- WAC | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61567840; called by muse, mutect2, varscan2
- WDCP | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV54592516; called by muse, mutect2, varscan2
- WDR27 | c.2231C>T p.S744L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV61210056; called by mutect2, varscan2
- WDR75 | c.1872C>G p.I624M | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV59105849; called by muse, mutect2, varscan2
- YTHDC2 | c.3562C>A p.P1188T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.19); catalogued as COSV50742413; called by muse, mutect2, varscan2
- ZNF257 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV101448118, COSV71306944; called by muse, mutect2, varscan2
- ZNF646 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs532190861, COSV54924767; called by muse, varscan2
- ARRDC3 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- ASH1L | c.3439C>T p.Q1147* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- CCDC150 | c.2489C>A p.A830D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.382); called by mutect2, varscan2
- EIF4G3 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 93/272 reads (34%) | called by muse, mutect2, varscan2
- IGHV1-18 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- KIAA1522 | c.1241C>G p.S414* (on ENST00000373480 / NM_001198972.2; = p.S473* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- NUP85 | c.1826C>G p.S609* | Nonsense Mutation (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2
- RELN | c.5310G>A p.W1770* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- SPEG | c.806C>G p.S269C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- AC004997.1 | c.1218G>A p.L406= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV57576074; called by muse, mutect2, varscan2
- ATP2B2 | c.1644C>G p.G548= (on ENST00000352432; = p.G514= on NM_001683.5) | Silent (SNP) | VAF 40/107 reads (37%) | catalogued as rs367837268, COSV59498221, COSV59504582; called by muse, mutect2, varscan2
- C20orf96 | c.375C>T p.L125= (on ENST00000360321 / NM_153269.3; = p.L124= on NM_080571.1) | Silent (SNP) | VAF 28/250 reads (11%) | catalogued as COSV64403715; called by muse, mutect2, varscan2
- CACNA1F | c.3606C>G p.L1202= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV59904936; called by muse, mutect2, varscan2
- COL10A1 | c.897G>A p.G299= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV54573297; called by muse, mutect2, varscan2
- FAM162A | c.201G>A p.Q67= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV51658456; called by muse, mutect2, varscan2
- FAT4 | c.1716C>G p.L572= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV67882794; called by muse, mutect2, varscan2
- FAT4 | c.2214C>A p.V738= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs753314680, COSV67888875; called by muse, mutect2, varscan2
- FAT4 | c.2778C>A p.G926= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV67888881; called by muse, mutect2, varscan2
- FAT4 | c.2997C>G p.L999= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as COSV67888905; called by muse, varscan2
- FAT4 | c.3537C>G p.V1179= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV67888932; called by muse, mutect2, varscan2
- FOXO3 | c.861G>A p.Q287= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV59628686; called by muse, mutect2, varscan2
- FRAS1 | c.11898G>A p.V3966= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV53616900; called by muse, mutect2
- HSD17B1 | c.186G>A p.T62= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as rs748307287, COSV56797824; called by muse, mutect2, varscan2
- IGSF10 | c.5397G>C p.V1799= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV56786408; called by muse, mutect2, varscan2
- LRRC37A2 | c.3711C>T p.F1237= | Silent (SNP) | VAF 19/181 reads (10%) | catalogued as COSV61003259; called by muse, mutect2, varscan2
- MAPK15 | c.1275G>T p.G425= | Silent (SNP) | VAF 73/148 reads (49%) | catalogued as COSV62028677; called by muse, mutect2, varscan2
- MTFMT | c.453G>A p.P151= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs200928562, COSV54978278; called by muse, mutect2, varscan2
- MYO1G | c.528G>A p.P176= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs571155365, COSV51855039; called by muse, mutect2, varscan2
- NAALAD2 | c.732G>A p.Q244= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV100428808, COSV58961840; called by muse, mutect2, varscan2
- NIPSNAP1 | c.576C>G p.L192= | Silent (SNP) | VAF 54/154 reads (35%) | catalogued as rs940586220, COSV53342808, COSV99331288; called by muse, mutect2, varscan2
- NOB1 | c.1188G>A p.R396= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV52062020, COSV52062232; called by muse, mutect2, varscan2
- OR9K2 | c.324C>T p.I108= (on ENST00000305377; = p.I86= on NM_001005243.1) | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs750684529, COSV59532247; called by muse, mutect2, varscan2
- PDE3B | c.1530G>A p.L510= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- PDPR | c.2586C>T p.F862= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1158834798, COSV55352050; called by muse, mutect2, varscan2
- PIM3 | c.933C>G p.L311= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV62259741; called by muse, varscan2
- PTPRS | c.1266C>T p.G422= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs372632192; called by muse, mutect2, varscan2
- SAR1B | c.504G>C p.L168= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV68391631; called by muse, mutect2, varscan2
- SCGB2A1 | c.222G>A p.L74= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV55275703, COSV55276291; called by muse, mutect2, varscan2
- SEMA3F | c.834C>T p.F278= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as COSV50030426, COSV99137538; called by muse, mutect2, varscan2
- SLC1A1 | c.870G>C p.L290= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV52053910; called by muse, mutect2, varscan2
- SLC32A1 | c.1443C>T p.L481= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV54146977; called by muse, mutect2
- SNX22 | c.426C>T p.F142= | Silent (SNP) | VAF 43/259 reads (17%) | catalogued as COSV55520391; called by muse, mutect2, varscan2
- TDRD6 | c.2124G>A p.Q708= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV60176283; called by muse, mutect2, varscan2
- TENM3 | c.5508C>T p.T1836= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV69310315; called by muse, mutect2, varscan2
- TMEM150B | c.372C>T p.F124= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV58593893; called by muse, mutect2, varscan2
- ZNF425 | c.1539C>T p.L513= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs373528690; called by muse, mutect2, varscan2
- ATP6AP1L | n.1687T>C | RNA (SNP) | VAF 12/55 reads (22%) | catalogued as rs1341384001, COSV66474977; called by muse, mutect2, varscan2
- CNOT1 | c.3523-874C>G | Intron (SNP) | VAF 38/124 reads (31%) | catalogued as COSV99800704; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847753 G>T | 5'Flank (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2, varscan2
- PANK2 | c.1536+486G>A | Intron (SNP) | VAF 41/149 reads (28%) | catalogued as rs868616864, COSV100262403; called by muse, mutect2, varscan2
- SERPINA3 | c.-38G>A | 5'UTR (SNP) | VAF 12/37 reads (32%) | catalogued as COSV67586331; called by muse, mutect2, varscan2
- SORCS1 | c.3371+218C>G | Intron (SNP) | VAF 34/73 reads (47%) | catalogued as COSV53872736, COSV99542498; called by muse, mutect2, varscan2
